Somatic mutation profile of tumor specimen TCGA-29-1766-01A (aliquot TCGA-29-1766-01A-01W-0633-09) from TCGA case TCGA-29-1766, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Peritoneum, NOS; FIGO stage: Stage IIIC; Tumor grade: G2; Age at diagnosis: 74.9 years (27,359 days).
Specimen TCGA-29-1766-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 35b320bf-7850-4255-a813-f64efd56e56c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-29-1766-10A (Blood Derived Normal), aliquot TCGA-29-1766-10A-01W-0634-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3ef9e2ca-2088-44c9-862b-dd5f7b3393c1

The open-access MAF lists 72 somatic variants for this specimen: 51 protein-altering or splice-affecting, 19 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 39, Silent 19, Nonsense Mutation 5, Frame Shift Ins 2, In Frame Del 1, Splice Site 1, Intron 1, Nonstop Mutation 1, Splice Region 1, Frame Shift Del 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AHCYL1 | c.1549C>A p.L517I | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT tolerated (0.31); PolyPhen benign (0.078); catalogued as COSV63208306, COSV63208814; called by muse, mutect2, varscan2
- AHNAK2 | c.11080G>T p.D3694Y | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV60917715; called by muse, mutect2, varscan2
- AKR1A1 | c.965A>G p.N322S | Missense Mutation (SNP) | VAF 64/130 reads (49%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as COSV61086600, COSV61086933; called by muse, mutect2, varscan2
- BACH1 | c.722C>A p.T241N | Missense Mutation (SNP) | VAF 18/160 reads (11%) | SIFT tolerated (0.2); PolyPhen benign (0.05); catalogued as COSV99728457; called by muse, varscan2
- BUB1 | c.1616+1G>A p.X539_splice | Splice Site (SNP) | VAF 35/64 reads (55%) | catalogued as COSV57064254; called by muse, mutect2, varscan2
- CCDC34 | c.1121A>T p.*374Lext*27 | Nonstop Mutation (SNP) | VAF 8/46 reads (17%) | catalogued as COSV60820865; called by muse, mutect2, varscan2
- CDH11 | c.1510C>T p.P504S | Missense Mutation (SNP) | VAF 29/58 reads (50%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.596); catalogued as rs762550510, COSV51764594; called by muse, mutect2, varscan2
- CR1L | c.1414C>G p.Q472E | Missense Mutation (SNP) | VAF 14/182 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as COSV99687713; called by muse, mutect2
- CYBB | c.932A>G p.Q311R | Missense Mutation (SNP) | VAF 25/88 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.133); catalogued as COSV66085537; called by muse, mutect2, varscan2
- DTNA | c.536C>G p.T179R | Missense Mutation (SNP) | VAF 36/71 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.65); catalogued as COSV51994185, COSV52007031; called by muse, mutect2, varscan2
- ENC1 | c.1185dup p.H396Afs*23 | Frame Shift Ins (INS) | VAF 4/40 reads (10%) | catalogued as rs770932086; called by pindel, varscan2
- EPHB2 | c.235C>T p.R79W | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0.013); catalogued as rs139122679; called by muse, mutect2, varscan2
- EVI2A | c.662G>T p.R221I | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as rs1316101259, COSV55985726, COSV55986125; called by muse, mutect2, varscan2
- GGT1 | c.328G>A p.A110T | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV50641099; called by muse, mutect2, varscan2
- GLRA4 | c.355C>T p.L119F | Missense Mutation (SNP) | VAF 27/98 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.738); catalogued as COSV65456114; called by muse, mutect2, varscan2
- GPALPP1 | c.61G>T p.E21* | Nonsense Mutation (SNP) | VAF 5/22 reads (23%) | catalogued as COSV100742138; called by muse, mutect2
- HOMER1 | c.26C>T p.T9I | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.953); catalogued as COSV56526792; called by muse, mutect2, varscan2
- HTR2C | c.622G>A p.V208M | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.522); catalogued as rs782783355, COSV52213889; called by muse, mutect2, varscan2
- ILVBL | c.365C>A p.A122E | Missense Mutation (SNP) | VAF 6/92 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99654980; called by muse, mutect2
- ITPR3 | c.6527C>T p.S2176F | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.707); catalogued as COSV100967691; called by muse, mutect2
- ITSN2 | c.4276C>G p.L1426V | Missense Mutation (SNP) | VAF 21/170 reads (12%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.458); catalogued as COSV61948481; called by muse, mutect2, varscan2
- JOSD1 | c.550C>A p.L184I | Missense Mutation (SNP) | VAF 4/70 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.331); catalogued as COSV99320173; called by muse, mutect2
- KALRN | c.6685C>G p.R2229G (on ENST00000360013 / NM_001024660.4; = p.R532G on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.5); catalogued as COSV99362477; called by muse, mutect2, varscan2
- MDN1 | c.271C>T p.H91Y | Missense Mutation (SNP) | VAF 49/399 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.777); catalogued as rs1160276839, COSV65522961; called by muse, mutect2, varscan2
- MECOM | c.355G>T p.D119Y | Missense Mutation (SNP) | VAF 26/261 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.428); catalogued as COSV72110522; called by muse, mutect2, varscan2
- MED13L | c.6223C>A p.R2075= | Splice Region (SNP) | VAF 11/69 reads (16%) | catalogued as COSV56121780, COSV99928089; called by muse, mutect2, varscan2
- MPP4 | c.940G>T p.E314* | Nonsense Mutation (SNP) | VAF 7/62 reads (11%) | catalogued as COSV59631862; called by muse, mutect2, varscan2
- MRPL15 | c.529G>T p.A177S | Missense Mutation (SNP) | VAF 14/204 reads (7%) | SIFT tolerated (0.26); PolyPhen benign (0.192); catalogued as COSV99477591; called by muse, mutect2
- MXRA5 | c.8472C>A p.Y2824* | Nonsense Mutation (SNP) | VAF 3/12 reads (25%) | catalogued as COSV99478082; called by muse, mutect2
- NEB | c.11982G>T p.Q3994H | Missense Mutation (SNP) | VAF 12/20 reads (60%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.891); catalogued as COSV51423580; called by muse, mutect2, varscan2
- NLRP4 | c.1766C>A p.S589Y | Missense Mutation (SNP) | VAF 14/87 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); catalogued as COSV100015893, COSV56715384; called by muse, mutect2, varscan2
- OR2J2 | c.722C>T p.T241I | Missense Mutation (SNP) | VAF 127/211 reads (60%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.844); catalogued as COSV65848074; called by muse, mutect2, varscan2
- PARP1 | c.1251dup p.K418Efs*24 | Frame Shift Ins (INS) | VAF 6/56 reads (11%) | catalogued as rs779960019; called by mutect2, pindel
- POTEF | c.735C>G p.Y245* | Nonsense Mutation (SNP) | VAF 4/20 reads (20%) | catalogued as COSV100664674, COSV62541545; called by mutect2, varscan2
- SCN5A | c.158G>A p.R53Q | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs199473049, CM097619, COSV60067556; ClinVar: not provided; called by muse, mutect2, varscan2
- SPECC1L | c.1498G>A p.E500K | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.769); catalogued as COSV100062850; called by muse, mutect2
- SPTB | c.2117G>A p.R706H | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.451); catalogued as rs201889680, COSV67632516; called by muse, mutect2, varscan2
- TP53 | c.828del p.C277Vfs*68 | Frame Shift Del (DEL) | VAF 74/153 reads (48%) | catalogued as COSV52796700, COSV52814873, COSV52939371; called by mutect2, pindel, varscan2
- TPMT | c.409G>T p.D137Y | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.587); catalogued as rs376217758; called by mutect2, varscan2
- TSHZ3 | c.499T>G p.W167G | Missense Mutation (SNP) | VAF 10/91 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV53673414; called by muse, mutect2, varscan2
- UNC5C | c.1066G>A p.V356I | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.824); catalogued as rs371874775; called by muse, mutect2, varscan2
- USP54 | c.3460A>G p.S1154G | Missense Mutation (SNP) | VAF 25/89 reads (28%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.024); catalogued as COSV60443513, COSV60445061; called by muse, mutect2, varscan2
- WDTC1 | c.1828C>T p.R610* (on ENST00000319394 / NM_001276252.2; = p.R609* on NM_015023.5) | Nonsense Mutation (SNP) | VAF 11/82 reads (13%) | catalogued as rs1163915622, COSV100088336, COSV60087140; called by mutect2, varscan2
- ZNF138 | c.823G>C p.E275Q (on ENST00000307355 / NM_001367572.1; = p.E249Q on NM_006524.4) | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.767); catalogued as COSV100245731, COSV56465620; called by muse, mutect2, varscan2
- ZNF626 | c.253C>A p.L85I | Missense Mutation (SNP) | VAF 23/170 reads (14%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.652); catalogued as COSV74129657; called by muse, mutect2, varscan2
- ZSWIM3 | c.1456C>A p.Q486K | Missense Mutation (SNP) | VAF 7/71 reads (10%) | SIFT tolerated (0.46); PolyPhen benign (0.027); catalogued as COSV99666747; called by muse, mutect2, varscan2
- C1orf87 | c.513_524del p.N172_A175del | In Frame Del (DEL) | VAF 29/111 reads (26%) | called by mutect2, pindel, varscan2
- CCL4 | c.44C>T p.A15V | Missense Mutation (SNP) | VAF 58/513 reads (11%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- DPM1 | c.38C>T p.S13F | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); called by muse, mutect2
- FCGBP | c.9202G>A p.D3068N | Missense Mutation (SNP) | VAF 20/94 reads (21%) | SIFT tolerated (0.44); PolyPhen benign (0.09); called by muse, mutect2, varscan2
- FCGBP | c.5599G>A p.D1867N | Missense Mutation (SNP) | VAF 25/116 reads (22%) | SIFT tolerated (0.27); PolyPhen benign (0.181); called by muse, mutect2, varscan2
- ATP2C1 | c.951G>A p.T317= | Silent (SNP) | VAF 13/184 reads (7%) | catalogued as rs147959633; called by muse, mutect2
- BASP1 | c.213C>T p.G71= | Silent (SNP) | VAF 7/16 reads (44%) | catalogued as rs750394431, COSV59471426; called by muse, varscan2
- FZD6 | c.1758G>A p.L586= | Silent (SNP) | VAF 3/42 reads (7%) | catalogued as COSV100708440; called by muse, mutect2
- IFITM3 | c.63G>A p.E21= | Silent (SNP) | VAF 6/39 reads (15%) | called by muse, mutect2
- KANK2 | c.2280C>T p.A760= (on ENST00000586659 / NM_001379562.1; = p.A768= on NM_015493.7 and 7 other RefSeq transcripts) | Silent (SNP) | VAF 8/42 reads (19%) | catalogued as COSV100763281; called by mutect2, varscan2
- KRT17 | c.900C>T p.I300= | Silent (SNP) | VAF 15/38 reads (39%) | catalogued as COSV60860951; called by muse, mutect2, varscan2
- LAMA2 | c.1896G>A p.L632= | Silent (SNP) | VAF 5/38 reads (13%) | catalogued as COSV101370642; called by muse, mutect2
- LRRC8C | c.2331G>C p.L777= | Silent (SNP) | VAF 10/78 reads (13%) | catalogued as COSV64998623; called by muse, mutect2, varscan2
- MCM6 | c.276G>C p.R92= | Silent (SNP) | VAF 15/122 reads (12%) | catalogued as COSV51466885; called by muse, mutect2, varscan2
- MYH3 | c.3529A>C p.R1177= | Silent (SNP) | VAF 18/97 reads (19%) | catalogued as COSV56865958; called by muse, mutect2, varscan2
- PCDHA4 | c.1365C>T p.F455= | Silent (SNP) | VAF 5/17 reads (29%) | catalogued as COSV63541716; called by muse, mutect2, varscan2
- PLCD3 | c.1392C>G p.P464= | Silent (SNP) | VAF 5/19 reads (26%) | catalogued as COSV100504250, COSV59560899; called by muse, varscan2
- PRAMEF7 | c.1332G>A p.R444= | Silent (SNP) | VAF 22/234 reads (9%) | catalogued as rs147766966; called by muse, mutect2
- RAB11FIP1 | c.3819G>A p.P1273= (on ENST00000330843 / NM_001002814.3; = p.P639= on NM_025151.5) | Silent (SNP) | VAF 17/112 reads (15%) | catalogued as rs142729002; called by muse, mutect2, varscan2
- SAMD9 | c.4638T>C p.N1546= | Silent (SNP) | VAF 12/136 reads (9%) | catalogued as rs375424281; called by muse, mutect2
- SAP130 | c.1230C>T p.T410= | Silent (SNP) | VAF 17/136 reads (13%) | catalogued as COSV52098218; called by muse, mutect2, varscan2
- SPECC1L | c.1500G>A p.E500= | Silent (SNP) | VAF 12/72 reads (17%) | catalogued as COSV100062854; called by muse, mutect2
- TIMP4 | c.279C>A p.I93= | Silent (SNP) | VAF 11/128 reads (9%) | catalogued as COSV55138583, COSV99826069; called by muse, mutect2
- VIL1 | c.522C>T p.I174= | Silent (SNP) | VAF 13/57 reads (23%) | catalogued as COSV50289216; called by muse, mutect2, varscan2
- BIRC8 | n.1695G>A | RNA (SNP) | VAF 7/106 reads (7%) | catalogued as COSV100136434; called by muse, mutect2
- TRPM3 | c.184-256729C>A | Intron (SNP) | VAF 39/119 reads (33%) | catalogued as COSV62679958; called by muse, mutect2, varscan2
